Somatic mutation profile of tumor specimen MMRF_1534_1_BM_CD138pos (aliquot MMRF_1534_1_BM_CD138pos_T1_KBS5U_L03482) from MMRF case MMRF_1534, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.2 years (23,435 days).
Specimen MMRF_1534_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4facea65-3b13-4858-ad6b-5c0dce62df97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1534_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1534_1_PB_CD3pos_C2_KBS5U_L03494; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8dad5be-714e-4920-b48a-f6b0a856400f

The open-access MAF lists 78 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 24, Intron 9, Silent 6, Nonsense Mutation 3, 5'UTR 2, RNA 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALKBH1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs372964712; called by muse, mutect2, varscan2
- CACNA2D2 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as rs1310940542; called by muse, mutect2, varscan2
- FAM47C | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 84/95 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs782216190; called by muse, mutect2, varscan2
- GPT | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV99477939; called by muse, mutect2, varscan2
- IGHV2-70 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377320995; called by muse, varscan2
- IGHV2-70 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370286145; called by muse, varscan2
- IGHV2-70 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs755395069; called by muse, varscan2
- IMP3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456051427; called by muse, mutect2, varscan2
- MAGI1 | c.3650G>T p.R1217L (on ENST00000402939 / NM_001033057.2; = p.A1275S on NM_015520.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV58332164; called by muse, mutect2, varscan2
- OR14C36 | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV58600839, COSV58602098; called by muse, mutect2, varscan2
- OSTN | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV59141137; called by muse, varscan2
- PGR | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs149186732; called by muse, mutect2, varscan2
- POF1B | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 78/80 reads (98%) | catalogued as COSV53136926; called by muse, mutect2, varscan2
- TRAF3 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs147686384; called by muse, mutect2, varscan2
- TTN | c.12283C>A p.P4095T (on ENST00000591111; = p.P4049T on NM_003319.4) | Missense Mutation (SNP) | VAF 47/101 reads (47%) | catalogued as rs1279181718; called by muse, mutect2, varscan2
- ABCC11 | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ABCC2 | c.2371G>T p.V791L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- C1orf127 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2
- CASS4 | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTN3 | c.199A>C p.S67R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DCC | c.3659T>C p.L1220P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- FAM200B | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MAP3K8 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MYBBP1A | c.986T>G p.V329G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MYBPHL | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEIL3 | c.671T>G p.M224R | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PARD6G | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC37A4 | c.1124-5G>C | Splice Region (SNP) | VAF 44/171 reads (26%) | called by muse, mutect2, varscan2
- SNTG1 | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2
- SYDE2 | c.1864A>T p.S622C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMCO1 | c.366A>C p.R122S (on ENST00000612311 / NM_001256164.1; = p.R71S on NM_019026.6) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); called by muse, varscan2
- TMCO1 | c.365G>A p.R122K (on ENST00000612311 / NM_001256164.1; = p.R71K on NM_019026.6) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, varscan2
- ZNF521 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDK19 | c.1467G>A p.Q489= | Silent (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- COX16 | c.123T>C p.Y41= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1186712211; called by muse, mutect2, varscan2
- FGF12 | c.114C>G p.R38= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- OGT | c.2913A>G p.K971= | Silent (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- TRIM71 | c.2151A>T p.S717= | Silent (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- USP22 | c.48G>A p.L16= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ADCY2 | c.*2146A>C | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- ADCY4 | c.2841+21C>T | Intron (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- ARSJ | c.-502C>T | 5'UTR (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- ATAD1 | c.*1743T>G | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- BACH1 | c.*1093A>G | 3'UTR (SNP) | VAF 23/48 reads (48%) | catalogued as rs991593763; called by muse, mutect2, varscan2
- BCHE | c.*6A>T | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- C1orf21 | c.*3323C>A | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- CA5BP1 | n.437A>T | RNA (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.*1089A>G | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.118C>A | RNA (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- EPHA3 | c.*304C>G | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- FAM171B | c.*1101C>G | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- FAT1 | c.13139-1344C>A | Intron (SNP) | VAF 44/80 reads (55%) | called by muse, mutect2, varscan2
- FOXG1 | c.*670G>A | 3'UTR (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- FOXK1 | c.*8140A>C | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- GRIN3A | c.*2203G>A | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- GSAP | c.1675-104T>G | Intron (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2
- IFT140 | c.3142-44A>T | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- IQCA1 | c.2135-11G>A | Intron (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- KIAA0100 | c.890+66A>G | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*2822C>T | 3'UTR (SNP) | VAF 8/16 reads (50%) | catalogued as rs959834278; called by muse, mutect2, varscan2
- MTTP | c.*674C>T | 3'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- NKTR | c.*2326_*2331del | 3'UTR (DEL) | VAF 18/34 reads (53%) | called by mutect2, pindel, varscan2
- NRIP1 | c.*3034C>T | 3'UTR (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- PCDH19 | c.*2810A>T | 3'UTR (SNP) | VAF 29/29 reads (100%) | called by muse, mutect2, varscan2
- PDGFD | c.*885C>T | 3'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- PLCB1 | c.*148C>T | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.295+228G>A | Intron (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- RPGRIP1 | chr14:21287953 T>A | 5'Flank (SNP) | VAF 70/163 reads (43%) | called by muse, mutect2, varscan2
- RPRD2 | c.436+201G>A | Intron (SNP) | VAF 28/98 reads (29%) | catalogued as rs782609836; called by muse, mutect2, varscan2
- SEMA3C | c.*543G>T | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- SESN3 | c.*3896C>T | 3'UTR (SNP) | VAF 34/96 reads (35%) | catalogued as rs980193017; called by muse, mutect2, varscan2
- SLC9C1 | c.*88A>C | 3'UTR (SNP) | VAF 76/154 reads (49%) | called by muse, varscan2
- SLIT2 | c.-118T>C | 5'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2
- TENT5B | c.*698C>T | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- THBS2 | c.*720C>T | 3'UTR (SNP) | VAF 37/60 reads (62%) | catalogued as rs1037011621; called by muse, mutect2, varscan2
- TRIM31 | c.418-76T>G | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, varscan2
- USH2A | c.*619T>C | 3'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
